Somatic mutation profile of tumor specimen TCGA-AP-A1DQ-01A (aliquot TCGA-AP-A1DQ-01A-11D-A135-09) from TCGA case TCGA-AP-A1DQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: High Grade; Age at diagnosis: 76.2 years (27,815 days).
Specimen TCGA-AP-A1DQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9e5c334-617b-4fb1-8a27-5d56cd458fb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1DQ-10A (Blood Derived Normal), aliquot TCGA-AP-A1DQ-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/799f81de-fe0e-45c0-852c-181040fc5b54

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 2, RNA 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 15/21 reads (71%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARID2 | c.5275G>A p.E1759K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100536949; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3204T>G p.N1068K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV62574144; called by muse, mutect2, varscan2
- CHD2 | c.3851T>G p.I1284S | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67708939; called by muse, mutect2, varscan2
- CYP26A1 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56418038; called by muse, mutect2, varscan2
- FUT11 | c.1346T>G p.M449R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV59541705; called by muse, mutect2, varscan2
- GMEB2 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs545692804, COSV56607079; called by muse, mutect2, varscan2
- HSD17B4 | c.790G>T p.V264F (on ENST00000414835 / NM_001199291.3; = p.V239F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV99820125; called by muse, mutect2
- KCNH7 | c.3380C>G p.S1127* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV59795892; called by muse, mutect2, varscan2
- LOXL4 | c.1706C>A p.A569E | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53256242, COSV53256546; called by muse, mutect2, varscan2
- MARK2 | c.1471C>T p.R491W (on ENST00000402010 / NM_001039469.2; = p.R490W on NM_004954.5) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1382894889, COSV59283175; called by muse, mutect2, varscan2
- NOS1 | c.2312C>T p.S771L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs150227193, COSV57608175; called by muse, mutect2, varscan2
- PHACTR3 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.186); catalogued as COSV63027663; called by muse, mutect2, varscan2
- POLE | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs150032060; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PSMA6 | c.505G>T p.G169* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99809280; called by muse, mutect2
- RIPK1 | c.278A>T p.E93V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52529370; called by muse, mutect2, varscan2
- ZNF777 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as rs1328934135, COSV56097562; called by muse, mutect2, varscan2
- LRRC47 | c.838_851del p.S280Efs*11 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- TRPM7 | c.5478G>C p.R1826S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDK13 | c.1929A>T p.R643= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs1370034759, COSV99476019; called by muse, mutect2
- CNTNAP5 | c.3021G>A p.S1007= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs768406833, COSV70482715; called by muse, mutect2, varscan2
- LRP1 | c.13434C>T p.G4478= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs769789309, COSV54510526; called by muse, mutect2, varscan2
- NPY5R | c.1194T>C p.I398= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV58451900; called by muse, mutect2, varscan2
- RIPOR2 | c.1641G>A p.E547= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs1349707501, COSV52421165; called by muse, mutect2, varscan2
- TNFAIP3 | c.42T>C p.N14= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99397204; called by mutect2, varscan2
- ZC4H2 | c.468C>T p.A156= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1396846097, COSV62003115; called by muse, mutect2
- DCHS2 | n.3424C>T | RNA (SNP) | VAF 24/97 reads (25%) | catalogued as COSV59725838; called by muse, mutect2, varscan2
- STAG3L2 | n.620C>T | RNA (SNP) | VAF 16/40 reads (40%) | catalogued as rs62476562; called by muse, mutect2, varscan2
- SUCO | chr1:172532687 C>G | 5'Flank (SNP) | VAF 7/37 reads (19%) | catalogued as COSV55265017; called by muse, mutect2, varscan2
